Somatic mutation profile of tumor specimen HCM-BROD-0115-C16-01A (aliquot HCM-BROD-0115-C16-01A-11D-A79L-36) from HCMI case HCM-BROD-0115-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 43.5 years (15,886 days).
Specimen HCM-BROD-0115-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d494bd1-26d5-4c50-a649-103f090447d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0115-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0115-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63c3d8b3-47a6-494a-ba9a-bfa21b6bb579

The open-access MAF lists 115 somatic variants for this specimen: 88 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 20, Frame Shift Del 7, Intron 5, Nonsense Mutation 5, In Frame Del 2, Nonstop Mutation 1, 3'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAL3ST2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 319/1051 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372108744, CM1412990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 187/703 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1384882995; called by muse, mutect2
- ADAMTS15 | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 141/542 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs1195459305; called by muse, mutect2, varscan2
- ANO4 | c.169G>T p.D57Y (on ENST00000392977 / NM_001286615.2; = p.D22Y on NM_178826.4) | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs373885901; called by muse, mutect2, varscan2
- CABLES2 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 38/775 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1226934537; called by muse, mutect2
- CACNA1G | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184328705; called by muse, mutect2, varscan2
- CD209 | c.772T>G p.W258G | Missense Mutation (SNP) | VAF 113/396 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52655421; called by muse, mutect2, varscan2
- CNTN1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61639394; called by muse, mutect2, varscan2
- CYP27C1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 142/526 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs763255213; called by muse, mutect2, varscan2
- DVL1 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 180/682 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs752206428; called by muse, mutect2, varscan2
- GABRA1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 204/412 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV50099403; called by muse, mutect2, varscan2
- GSTO1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292504288; called by muse, mutect2, varscan2
- HSPH1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 103/415 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs368302544, COSV60713590; called by muse, mutect2, varscan2
- LRP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 121/440 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs147295930, COSV55555420; called by muse, mutect2, varscan2
- NCOR2 | c.2024A>G p.K675R | Missense Mutation (SNP) | VAF 110/418 reads (26%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as rs760401324; called by muse, mutect2, varscan2
- NLRP5 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 85/580 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66765068, COSV66765984; called by muse, mutect2, varscan2
- NSD3 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 104/475 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs1456616250; called by muse, mutect2, varscan2
- OLFM3 | c.632G>A p.R211H (on ENST00000338858 / NM_001288821.1; = p.R191H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776719691, COSV58801848, COSV58804479; called by muse, mutect2, varscan2
- PCDHGA5 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 381/667 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs760966863, COSV54003473; called by muse, mutect2, varscan2
- PNPLA8 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 112/417 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769232930; called by muse, mutect2, varscan2
- RALBP1 | c.1934C>A p.S645* | Nonsense Mutation (SNP) | VAF 293/707 reads (41%) | catalogued as COSV50034210; called by muse, mutect2, varscan2
- RYR3 | c.10099G>A p.V3367M (on ENST00000389232; = p.V3368M on NM_001036.6) | Missense Mutation (SNP) | VAF 118/472 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761453884, COSV66777080; called by muse, varscan2
- TMCO6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 222/365 reads (61%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs753691038; called by muse, mutect2, varscan2
- ZC2HC1C | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 131/365 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs780067829; called by muse, mutect2, varscan2
- AC026316.4 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 54/364 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.1937C>G p.A646G | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AL121899.2 | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 19/754 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ANK2 | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- AQP6 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 226/804 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ASH1L | c.7574A>T p.Y2525F (on ENST00000368346 / NM_001366177.2; = p.Y2520F on NM_018489.3) | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP8A2 | c.1659A>T p.E553D | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCORL1 | c.3765A>C p.E1255D | Missense Mutation (SNP) | VAF 158/362 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CCL21 | c.382_398del p.S128Afs*5 | Frame Shift Del (DEL) | VAF 162/407 reads (40%) | called by mutect2, pindel, varscan2
- CCN2 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK5R1 | c.783C>A p.C261* | Nonsense Mutation (SNP) | VAF 23/549 reads (4%) | called by muse, mutect2
- CFAP70 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CILP2 | c.1360del p.V454Sfs*4 | Frame Shift Del (DEL) | VAF 142/790 reads (18%) | called by mutect2, pindel, varscan2
- CNOT1 | c.3541_3543del p.K1181del | In Frame Del (DEL) | VAF 77/481 reads (16%) | called by mutect2, pindel, varscan2
- COL2A1 | c.2723C>A p.P908Q | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNNB1 | c.2346A>C p.*782Yext*4 | Nonstop Mutation (SNP) | VAF 166/289 reads (57%) | called by muse, mutect2, varscan2
- CYP21A2 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 143/991 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAAM2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, varscan2
- DOCK10 | c.6236C>A p.A2079D | Missense Mutation (SNP) | VAF 130/470 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DPEP2 | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 42/610 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); called by muse, mutect2
- DRP2 | c.2426A>T p.Q809L | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- DYRK3 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 293/481 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYTN | c.1013A>C p.D338A | Missense Mutation (SNP) | VAF 91/411 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- EEF2K | c.2030C>G p.T677R | Missense Mutation (SNP) | VAF 107/707 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- EFHC1 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 121/465 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EPB41L1 | c.56_72del p.P19Rfs*22 | Frame Shift Del (DEL) | VAF 279/662 reads (42%) | called by pindel, varscan2
- EVC2 | c.2650T>C p.W884R | Missense Mutation (SNP) | VAF 125/708 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FABP12 | c.247A>C p.S83R | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FAT4 | c.2642_2688del p.I881Nfs*25 | Frame Shift Del (DEL) | VAF 110/535 reads (21%) | called by mutect2, pindel
- FCRL4 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 58/540 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FNDC3B | c.2055_2061del p.H685Qfs*4 | Frame Shift Del (DEL) | VAF 50/439 reads (11%) | called by mutect2, pindel, varscan2
- GATAD2A | c.1870del p.R624Afs*147 | Frame Shift Del (DEL) | VAF 101/570 reads (18%) | called by mutect2, pindel, varscan2
- GNAQ | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIA4 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 107/526 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HDGF | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 185/817 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); called by muse, mutect2
- IL5RA | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 186/330 reads (56%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.621G>T p.R207S | Missense Mutation (SNP) | VAF 127/642 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LHX1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 311/1088 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LIMCH1 | c.1272A>C p.R424S | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAZ | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 98/498 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MCOLN2 | c.879T>G p.F293L | Missense Mutation (SNP) | VAF 227/379 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MEX3B | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 155/664 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MPEG1 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 191/578 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPP3 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 186/595 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.36962A>G p.E12321G | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH7 | c.1676A>C p.K559T | Missense Mutation (SNP) | VAF 34/666 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- NUP88 | c.1754A>G p.E585G | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- OR2A2 | c.933A>T p.R311S | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- OR2C1 | c.337_341del p.I113Afs*7 | Frame Shift Del (DEL) | VAF 130/568 reads (23%) | called by mutect2, pindel, varscan2
- OR6T1 | c.446G>C p.W149S | Missense Mutation (SNP) | VAF 54/646 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OSBPL1A | c.207+1G>A p.X69_splice | Splice Site (SNP) | VAF 68/268 reads (25%) | called by muse, mutect2, varscan2
- PBRM1 | c.2972A>T p.K991I | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PTGS1 | c.1369A>C p.M457L | Missense Mutation (SNP) | VAF 150/667 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABEP2 | c.267_269del p.I89_L90delinsM | In Frame Del (DEL) | VAF 76/440 reads (17%) | called by mutect2, pindel, varscan2
- RC3H2 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 316/691 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF217 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 138/514 reads (27%) | called by muse, mutect2, varscan2
- SH3YL1 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 99/354 reads (28%) | called by muse, mutect2, varscan2
- SLC18A1 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPSB1 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 93/631 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTA1 | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 198/457 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TNS2 | c.3078C>G p.S1026R (on ENST00000314250 / NM_170754.4; = p.S1036R on NM_015319.2) | Missense Mutation (SNP) | VAF 320/1027 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TTLL11 | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 286/600 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); called by mutect2, varscan2
- WRAP73 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 265/446 reads (59%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF804A | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 166/478 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF18 | c.156G>A p.P52= | Silent (SNP) | VAF 191/705 reads (27%) | called by muse, mutect2, varscan2
- BOD1L1 | c.5433T>C p.D1811= | Silent (SNP) | VAF 28/964 reads (3%) | called by muse, mutect2
- EPB41L1 | c.78C>T p.A26= | Silent (SNP) | VAF 318/690 reads (46%) | catalogued as rs372761608; called by muse, varscan2
- EVC | c.2814C>T p.P938= | Silent (SNP) | VAF 105/488 reads (22%) | called by muse, mutect2, varscan2
- IQCA1L | c.2407T>C p.L803= | Silent (SNP) | VAF 153/554 reads (28%) | called by muse, mutect2, varscan2
- IQCA1L | c.1980G>T p.L660= | Silent (SNP) | VAF 173/614 reads (28%) | called by muse, mutect2, varscan2
- KMT2D | c.4932C>T p.D1644= | Silent (SNP) | VAF 135/534 reads (25%) | called by muse, mutect2, varscan2
- LNX2 | c.963C>T p.G321= | Silent (SNP) | VAF 279/505 reads (55%) | called by muse, mutect2, varscan2
- M6PR | c.237G>A p.R79= | Silent (SNP) | VAF 37/616 reads (6%) | catalogued as rs1475412328; called by muse, mutect2
- MAN2A2 | c.1251C>T p.N417= | Silent (SNP) | VAF 132/590 reads (22%) | catalogued as rs779129942; called by muse, mutect2, varscan2
- MUC16 | c.312G>T p.S104= | Silent (SNP) | VAF 105/418 reads (25%) | catalogued as rs375785587; called by muse, mutect2, varscan2
- PAPPA | c.840T>C p.A280= | Silent (SNP) | VAF 49/832 reads (6%) | called by muse, mutect2
- PDE4A | c.945A>G p.R315= (on ENST00000380702 / NM_001111307.2; = p.R76= on NM_006202.3) | Silent (SNP) | VAF 136/552 reads (25%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.2121G>A p.P707= | Silent (SNP) | VAF 208/798 reads (26%) | called by muse, mutect2, varscan2
- PPP4R1 | c.1416T>G p.L472= (on ENST00000400556 / NM_001042388.3; = p.L455= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 346/794 reads (44%) | called by muse, mutect2
- SFTPA2 | c.138G>A p.G46= | Silent (SNP) | VAF 149/566 reads (26%) | catalogued as rs746354270; called by muse, mutect2, varscan2
- SLC12A8 | c.1296C>T p.H432= | Silent (SNP) | VAF 121/784 reads (15%) | catalogued as rs1274129134; called by muse, mutect2, varscan2
- TCF4 | c.450G>A p.Q150= | Silent (SNP) | VAF 124/453 reads (27%) | catalogued as rs908969397; called by muse, mutect2, varscan2
- TDO2 | c.540T>C p.Y180= | Silent (SNP) | VAF 124/481 reads (26%) | called by muse, mutect2, varscan2
- ZNF804A | c.1926G>A p.Q642= | Silent (SNP) | VAF 82/374 reads (22%) | catalogued as COSV100168139, COSV100170470; called by muse, mutect2, varscan2
- CCDC74B | c.295+305G>A | Intron (SNP) | VAF 141/528 reads (27%) | catalogued as rs1394222364; called by muse, mutect2, varscan2
- IGFN1 | c.1241+163T>G | Intron (SNP) | VAF 108/743 reads (15%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1248-3571_1248-3543del | Intron (DEL) | VAF 39/156 reads (25%) | called by mutect2, pindel, varscan2
- NAF1 | chr4:163126983 T>C | 3'Flank (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- NKX6-3 | c.553-562C>G | Intron (SNP) | VAF 167/625 reads (27%) | called by muse, mutect2, varscan2
- PLET1 | c.*120T>G | 3'UTR (SNP) | VAF 38/618 reads (6%) | called by muse, mutect2
- SLA | c.-40-23C>T | Intron (SNP) | VAF 115/666 reads (17%) | called by muse, mutect2, varscan2
